Somatic mutation profile of tumor specimen TCGA-DX-AB30-01A (aliquot TCGA-DX-AB30-01A-11D-A38Z-09) from TCGA case TCGA-DX-AB30, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 53.9 years (19,698 days).
Specimen TCGA-DX-AB30-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c85ed62d-7751-4dae-9092-11ff0a3db33f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-AB30-10A (Blood Derived Normal), aliquot TCGA-DX-AB30-10A-01D-A38Z-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d55515fd-2e63-4b5f-a284-f06372033866

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 7, Silent 3, Frame Shift Del 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.833C>A p.P278H | Missense Mutation (SNP) | VAF 38/39 reads (97%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876659802, CM961376, COSV52661225, COSV52665769, COSV52678063; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- EHD2 | c.182T>G p.V61G | Missense Mutation (SNP) | VAF 67/73 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99621585; called by muse, mutect2, varscan2
- GRP | c.260T>C p.L87P | Missense Mutation (SNP) | VAF 43/45 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99900870; called by muse, mutect2, varscan2
- MYO15A | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as rs934249137, COSV52761349; called by muse, mutect2, varscan2
- NTNG2 | c.1240A>G p.I414V | Missense Mutation (SNP) | VAF 54/54 reads (100%) | SIFT tolerated (0.63); PolyPhen benign (0.06); catalogued as COSV100647212; called by muse, mutect2, varscan2
- RAD54L | c.272-1G>T p.X91_splice | Splice Site (SNP) | VAF 3/47 reads (6%) | catalogued as COSV100914750; called by muse, mutect2
- ZMYND11 | c.87G>C p.K29N | Missense Mutation (SNP) | VAF 56/64 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100555813; called by muse, mutect2, varscan2
- ZNF106 | c.3463T>C p.F1155L | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV55519032, COSV99782117; called by muse, mutect2
- CXCL8 | c.144_165del p.F48Lfs*14 | Frame Shift Del (DEL) | VAF 60/70 reads (86%) | called by mutect2, pindel, varscan2
- EED | c.816del p.N272Kfs*44 | Frame Shift Del (DEL) | VAF 90/127 reads (71%) | called by mutect2, pindel, varscan2
- NF1 | c.921dup p.A308Cfs*7 | Frame Shift Ins (INS) | VAF 62/87 reads (71%) | called by mutect2, pindel, varscan2
- CHDH | c.642C>T p.T214= | Silent (SNP) | VAF 63/64 reads (98%) | catalogued as COSV100179533; called by muse, mutect2, varscan2
- HUNK | c.2127G>T p.G709= | Silent (SNP) | VAF 49/55 reads (89%) | catalogued as rs1197298284, COSV99527967; called by muse, mutect2, varscan2
- PDSS2 | c.1065C>T p.G355= | Silent (SNP) | VAF 33/38 reads (87%) | catalogued as COSV100942323; called by muse, mutect2, varscan2
